Gene-level copy-number profile of tumor specimen ALCH-ADXC-TTP1-A from ALCHEMIST case ALCH-ADXC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.2 years (22,725 days).
Specimen ALCH-ADXC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42daac6a-1755-4cb7-b744-064f279dd829.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADXC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,765 have no estimate.
https://portal.gdc.cancer.gov/files/1d295f5b-4624-4192-b9a3-06b8b5a715e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 288; copy number 1: 14,541; copy number 2: 42,685; copy number 3: 1,005; copy number 4: 243; copy number 5: 65; copy number 6: 13; copy number 7: 8; copy number 8: 1; copy number 9: 6; copy number 10: 1; copy number 12: 1; copy number 61: 1.

Homozygous deletions (total copy number 0; autosomes only): 288 genes in 110 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,979,576–9,026,345, 2 genes: RN7SL451P, SLC2A7.
- chr1:9,728,926–9,823,984, 2 genes (within-gene range 0–1): CLSTN1, MZT1P1.
- chr1:13,279,125–13,421,328, 9 genes: RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20.
- chr1:28,142,737–28,193,936, 2 genes: RNU6-176P, PTAFR.
- chr1:51,973,410–51,996,039, 3 genes (within-gene range 0–1): RNA5SP48, AL445685.2, RN7SL290P.
- chr1:113,073,198–113,132,260, 2 genes (within-gene range 0–1): LRIG2, RLIMP2.
- chr2:90,121,786–91,621,421, 15 genes (within-gene range 0–2): IGKV2D-14, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,686,102–91,723,605, 2 genes: AC027612.2, NKAIN1P2.
- chr2:237,563,165–237,567,175, 2 genes: RNU6-1140P, PRLH.
- chr3:51,385,291–51,500,002, 3 genes: MANF, RBM15B, DCAF1.
- chr4:49,486,926–49,508,806, 3 genes: AC119751.3, ANKRD20A17P, AC119751.5.
- chr4:150,970,671–151,104,642, 4 genes (within-gene range 0–1): RNA5SP168, AK4P6, RPS3A, SNORD73B.
- chr5:57,081,745–57,122,624, 2 genes: AC034244.1, AC034244.2.
- chr5:69,160,806–69,210,357, 5 genes: AC010273.1, SNORA50D, CCNB1, AC022107.1, CENPH.
- chr5:70,900,669–71,025,339, 4 genes: SERF1A, SMN1, AC139834.1, NAIP.
- chr5:181,178,821–181,194,429, 2 genes (within-gene range 0–1): LINC01962, AC008443.4.
- chr7:152,435,695–152,465,549, 3 genes (within-gene range 0–2): FABP5P3, CCT8L1P, LINC01003.
- chr8:20,246,165–20,303,963, 3 genes (within-gene range 0–1): LZTS1, LZTS1-AS1, RNA5SP257.
- chr8:33,523,154–33,600,023, 6 genes: AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:37,908,738–37,966,599, 4 genes: RN7SL709P, GOT1L1, AC144573.1, ADRB3.
- chr8:43,018,424–43,202,855, 6 genes (within-gene range 0–1): AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT.
- chr8:97,772,313–97,853,013, 3 genes: Y_RNA, LAPTM4B, AP003357.1.
- chr9:60,914,407–61,666,386, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr10:68,477,998–68,544,833, 4 genes: SLC25A16, RPL26P27, Y_RNA, TMEM14DP.
- chr11:62,615,296–62,665,210, 5 genes (within-gene range 0–2): B3GAT3, GANAB, INTS5, AP001458.2, C11orf98.
- chr12:118,063,593–118,136,026, 2 genes (within-gene range 0–1): VSIG10, AC131238.1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:18,645,044–18,667,370, 3 genes: CR383656.8, CR383656.11, CR383656.3.
- chr14:19,024,090–19,055,551, 2 genes: AL589182.1, GRAMD4P4.
- chr15:43,804,492–43,868,412, 3 genes (within-gene range 0–1): MFAP1, WDR76, Y_RNA.
- chr16:28,878,405–28,990,784, 13 genes: ATP2A1, ATP2A1-AS1, AC133550.1, RABEP2, CD19, NFATC2IP, AC109460.2, MIR4517, AC109460.1, SPNS1, AC109460.3, LAT, AC109460.4.
- chr16:70,251,983–70,289,707, 2 genes (within-gene range 0–1): AARS1, RN7SL279P.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–3): AC092143.1, AC092143.2, TUBB3.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr20:31,605,283–31,607,240, 2 genes: ID1, MIR3193.
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,328,411–13,016,692, 12 genes: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr22:17,734,138–17,779,481, 3 genes: BID, MIR3198-1, LINC00528.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–1): AC016026.1, AC016026.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 96 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,814,056–2,817,767, 2 genes, copy number 6: AL592464.3, AL592464.1.
- chr1:13,254,212–13,275,627, 2 genes, copy number 5: PRAMEF5, PRAMEF32P.
- chr1:30,409,560–30,421,108, 2 genes, copy number 5: AL161638.2, AL161638.1.
- chr1:32,816,767–34,165,842, 31 genes, copy number 5–10 (within-gene range 4–10): S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42.
- chr1:36,630,335–36,630,857, 1 gene, copy number 5: FTLP18.
- chr1:39,838,110–39,883,511, 2 genes, copy number 5: TRIT1, Y_RNA.
- chr1:41,014,590–41,043,890, 1 gene, copy number 5 (within-gene range 4–5): SLFNL1-AS1.
- chr1:41,027,200–41,242,154, 2 genes, copy number 5: SCMH1, RPL23AP17.
- chr1:119,794,017–120,100,779, 7 genes, copy number 5–7: REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1.
- chr1:120,489,860–120,914,238, 9 genes, copy number 6–9 (within-gene range 4–11): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr5:1,544,107–1,551,710, 1 gene, copy number 5: AC091849.2.
- chr5:1,598,920–1,634,005, 2 genes, copy number 5 (within-gene range 2–5): AC026412.1, AC026412.2.
- chr5:70,751,184–70,795,914, 2 genes, copy number 7: GUSBP16, AC139272.1.
- chr8:142,764,334–142,778,224, 3 genes, copy number 5 (within-gene range 2–5): LYNX1-SLURP2, SLURP2, LYNX1.
- chr8:142,834,138–142,834,940, 1 gene, copy number 5 (within-gene range 3–5): AC083841.3.
- chr8:143,723,933–143,738,234, 1 gene, copy number 12 (within-gene range 1–12): FAM83H.
- chr8:143,758,153–143,771,870, 1 gene, copy number 5: AC105219.3.
- chr9:137,007,234–137,037,957, 3 genes, copy number 5 (within-gene range 1–5): ABCA2, C9orf139, FUT7.
- chr9:137,048,107–137,054,061, 2 genes, copy number 5: ENTPD2, AL807752.4.
- chr9:137,077,517–137,084,539, 1 gene, copy number 9: UAP1L1.
- chr11:837,356–842,529, 1 gene, copy number 5 (within-gene range 0–5): POLR2L.
- chr11:1,049,880–1,055,749, 1 gene, copy number 6: LINC02688.
- chr14:18,967,434–19,003,752, 3 genes, copy number 5: POTEM, AL929601.3, RNU6-1239P.
- chr14:105,583,731–105,588,395, 1 gene, copy number 8: IGHA2.
- chr16:1,064,093–1,078,731, 2 genes, copy number 5: SSTR5-AS1, AC009041.2.
- chr16:1,111,627–1,113,399, 1 gene, copy number 7: AL031598.1.
- chr16:1,240,379–1,263,845, 4 genes, copy number 5–7: TPSAB1, TPSD1, AC120498.2, PRSS29P.
- chr16:32,475,051–32,478,250, 1 gene, copy number 61: ABCD1P3.
- chr16:88,856,220–88,866,660, 2 genes, copy number 5 (within-gene range 3–5): TRAPPC2L, PABPN1L.
- chr16:89,696,357–89,701,705, 1 gene, copy number 6 (within-gene range 1–6): SPATA2L.
- chr19:39,638,685–39,660,647, 3 genes, copy number 5: AC005176.1, RPS29P30, LGALS16.

Autosomal genes at a single copy (total copy number 1): 11,685. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
